Gene-level copy-number profile of specimen HCM-SANG-1083-C16-85A-01D-A80T-32 from HCMI case HCM-SANG-1083-C16, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G3.
Specimen HCM-SANG-1083-C16-85A-01D-A80T-32: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d6efced4-dfe7-4baa-867e-e525acc5d01d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-1083-C16-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,753 have no estimate.
https://portal.gdc.cancer.gov/files/8a517192-af1a-40c9-a46c-35a0b59f070d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 16; copy number 1: 1,873; copy number 2: 29,666; copy number 3: 19,685; copy number 4: 5,680; copy number 5: 537; copy number 6: 1,145; copy number 7: 17; copy number 12: 48; copy number 13: 14; copy number 14: 3; copy number 15: 11; copy number 18: 4; copy number 20: 50; copy number 21: 17; copy number 22: 1; copy number 24: 2; copy number 25: 9; copy number 26: 3; copy number 36: 29; copy number 42: 4; copy number 47: 17; copy number 49: 16; copy number 50: 23.

Homozygous deletions (total copy number 0; autosomes only): 12 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:4,126,659–4,150,421, 2 genes: OR7E103P, UNC93B4.
- chr18:39,206,917–39,800,322, 8 genes: MIR924HG, AC011139.1, RPL7AP66, MIR924, AC099845.1, MIR5583-2, MIR5583-1, RNU6-1242P.
- chr20:15,021,553–15,022,958, 2 genes (within-gene range 0–5): RNU6-1159P, RNU6-115P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,950 genes in 20 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:142,131,178–143,964,156, 24 genes, copy number 5 (within-gene range 3–5): AC078882.1, UBE2V1P14, RRN3P4, KYNU, SFXN4P1, ARHGAP15, MTCYBP11, MTND6P11, MTND5P24, MTND4P22, MTND4LP12, MTND3P9, MTCO3P5, MTATP6P5, MTCO2P5, AC013437.1, AC079793.1, AC092652.2, ARHGAP15-AS1, AC092652.1, AC079584.2, AC079584.1, Y_RNA, AC016910.1.
- chr3:94,935,760–96,777,683, 14 genes, copy number 6–7: AC140059.1, WDR82P1, LINC00879, RPS18P6, MTHFD2P1, AC107304.1, HNRNPKP4, MIR8060, AC107015.1, RNU6-1094P, MTRNR2L12, RPL18AP8, RCC2P5, CDV3P1.
- chr3:98,053,374–99,018,562, 40 genes, copy number 6–7: OR5BM1P, OR5AC1, OR5AC2, AC117460.1, OR5AC4P, POU5F1P7, OR5H1, OR5H14, OR5H15, OR5H5P, OR5H3P, OR5H4P, AC117473.1, OR5H7P, OR5H6, OR5H2, OR5H8, OR5K4, OR5K3, UBFD1P1, OR5K1, OR5K2, CLDND1, AC021660.3, AC021660.2, RPL38P4, GPR15, AC021660.4, CPOX, AC021660.1, WWP1P1, ST3GAL6-AS1, ST3GAL6, PDLIM1P4, DCBLD2, RNU6-26P, AC091212.1, RNU6-1263P, LINC00973, U7.
- chr3:133,746,040–134,250,859, 10 genes, copy number 5 (within-gene range 4–5): TF, AC080128.1, SRPRB, AC080128.2, RAB6B, C3orf36, SLCO2A1, LINC02000, RYK, HMGB3P14.
- chr3:134,437,605–134,575,017, 5 genes, copy number 5: HMGB3P13, MIR4788, ANAPC13, CEP63, AC026117.1.
- chr3:142,306,607–142,448,062, 3 genes, copy number 5: XRN1, RNU6-1294P, RNU1-100P.
- chr3:149,761,100–149,968,385, 1 gene, copy number 5 (within-gene range 4–5): ANKUB1.
- chr3:149,812,770–150,466,431, 17 genes, copy number 5: RNF13, RNU6-720P, NPM1P29, PFN2, AC117395.1, TMEM183B, PPIAP73, HNRNPA1P24, AC117386.2, AC022494.1, LINC01998, RPL32P9, AC117386.1, LINC01213, U2, LINC01214, TSC22D2.
- chr3:151,425,384–151,499,806, 3 genes, copy number 5 (within-gene range 4–5): IGSF10, MRPL42P6, AC117454.1.
- chr9:12,134–4,348,392, 55 genes, copy number 5 (within-gene range 4–5): DDX11L5, WASHC1, MIR1302-9HG, MIR1302-9, FAM138C, AL449043.2, PGM5P3-AS1, AL449043.1, LINC01388, FOXD4, CBWD1, DOCK8-AS1, DOCK8, AL158832.1, AL161725.1, KANK1, RPL12P25, AL161725.2, AL392089.1, RNU6-1327P, EIF1P1, AL136979.1, DMRT1, DMRT3, RNU6-1073P, H3P29, LINC01230, DMRT2, AL356498.1, RPS27AP14, AL358934.1, RNA5SP279, AL591644.1, SMARCA2, AL359076.1, RNU2-25P, RN7SL592P, VLDLR-AS1, AL353614.1, VLDLR, AL450467.1, KCNV2, PUM3, GPS2P1, ATP5PDP2, CARM1P1, LINC01231, RFX3, AL354941.1, RFX3-AS1, AL354977.2, AL354977.1, GLIS3, AL137071.1, GLIS3-AS1.
- chr9:4,299,390–7,961,224, 82 genes, copy number 5 (broad region; genes not listed).
- chr14:20,179,189–20,528,959, 30 genes, copy number 5: OR11G1P, OR11G2, OR11H5P, OR11H6, OR11H7, OR11H4, TTC5, AL356019.2, AL356019.1, CCNB1IP1, AL355075.6, SNORA79B, SNORD126, AL355075.4, RPPH1, PARP2, AL355075.1, TEP1, RNA5SP382, KLHL33, AL355075.5, OSGEP, AL355075.2, APEX1, PIP4P1, PNP, AL355075.3, RNASE10, PTCD2P1, SETP1.
- chr17:26,981,694–27,084,036, 6 genes, copy number 5: AC069061.1, AC069061.2, PDLIM1P3, GTF2IP6, VN1R71P, TUFMP1.
- chr17:36,183,235–36,334,759, 10 genes, copy number 5: AC243829.1, CCL3L3, CCL4L2, AC243829.5, AC243829.3, AC243829.6, TBC1D3I, AC233699.1, Y_RNA, TBC1D3G.
- chr17:36,861,674–41,865,423, 251 genes, copy number 12–50 (broad region; genes not listed).
- chr17:46,292,733–46,337,794, 2 genes, copy number 6 (within-gene range 1–6): LRRC37A, RN7SL656P.
- chr20:87,250–16,053,197, 284 genes, copy number 5 (within-gene range 0–6) (broad region; genes not listed).
- chr20:14,884,250–14,929,528, 1 gene, copy number 5 (within-gene range 1–5): MACROD2-AS1.
- chr20:15,552,157–64,327,972, 1,109 genes, copy number 5–6 (broad region; genes not listed).
- chr22:18,906,028–18,947,732, 3 genes, copy number 5 (within-gene range 3–5): DGCR6, AC007326.4, PRODH.

Autosomal genes at a single copy (total copy number 1): 1,010. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
